CGCI case HTMCP-03-06-02199 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0c29ce4a-22ef-4b93-b9cc-b5a639168c2c

Demographics
Sex at birth: female; Race: black or african american; Age at index: 68 years; Vital status: Dead; Days to death: 450 days (1.2 years).

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2015; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: N0; AJCC clinical M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 450 days (1.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 37 days; Days to treatment end: 108 days; Treatment dose: 54; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 5400; Treatment anatomic sites: Pelvis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 367 days (1.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 450.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 42.3 kg; Height: 156 cm; BMI: 17.4; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.
- Day 0: Comorbidities: Helicobacter pylori Infection.
- Day 0: Risk factors: Helicobacter pylori-Associated Gastritis.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples)
- Sample HTMCP-03-06-02199-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02199-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 10; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 11; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative; History relevant infectious diagnosis: Helicobacter pylori.
- Follow-up form 2, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation.
- Follow-up form 2, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes; Radiation therapy total dosage: 54.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02199-01A-01D-6194:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet_20191105.xlsx, for sample HTMCP-03-06-02199-01A-02D-6194:
- % tumour top: 90
- % tumour bottom: 90
